Gene-level copy-number profile of tumor specimen TCGA-DM-A28K-01A from TCGA case TCGA-DM-A28K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.1 years (27,428 days).
Specimen TCGA-DM-A28K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d9ccd335-07c2-44cc-8146-09e593b2de03.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A28K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/158f3210-61a3-4ca1-943e-89e7d0d8a77e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,609; copy number 2: 44,809; copy number 3: 9,542; copy number 4: 1,828; copy number 6: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A28K-01A-21D-A16U-01): tumor purity 0.88, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:38,655,209–43,277,535, 31 genes, copy number 6: AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4.

Autosomal genes at a single copy (total copy number 1): 1,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
